Gene-level copy-number profile of tumor specimen TCGA-22-5479-01A from TCGA case TCGA-22-5479, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.5 years (23,563 days).
Specimen TCGA-22-5479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a619460f-c259-44bf-b675-75b0b15780e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5479-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa2779cd-6923-40d6-9d73-92b7a751aeac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11; copy number 2: 17,896; copy number 3: 19,254; copy number 4: 11,301; copy number 5: 5,276; copy number 6: 4,805; copy number 7: 383; copy number 8: 646; copy number 9: 70; copy number 11: 59; copy number 12: 53; copy number 16: 42; copy number 18: 10; copy number 23: 2; copy number 25: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5479-01A-31D-1943-01): tumor purity 0.28, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,316 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,926,567–104,226,678, 3 genes, copy number 6: AL136455.1, AC092506.1, FTLP17.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr2:38,814–191,425,389, 3,222 genes, copy number 5 (broad region; genes not listed).
- chr3:90,030,284–198,222,513, 1,806 genes, copy number 6–8 (broad region; genes not listed).
- chr5:13,144,000–42,973,092, 414 genes, copy number 5–25 (broad region; genes not listed).
- chr8:150,584–6,648,508, 86 genes, copy number 6 (broad region; genes not listed).
- chr8:6,622,124–6,622,220, 1 gene, copy number 6: MIR8055.
- chr9:452,492–1,164,867, 17 genes, copy number 6: AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14.
- chr9:3,824,127–4,348,392, 1 gene, copy number 7 (within-gene range 4–7): GLIS3.
- chr9:4,070,906–4,386,556, 3 genes, copy number 7: AL359095.1, AL162419.1, RNU6-694P.
- chr9:23,291,544–43,045,120, 448 genes, copy number 5–18 (broad region; genes not listed).
- chr12:66,767–10,599,669, 394 genes, copy number 6–12 (broad region; genes not listed).
- chr12:56,511,002–60,419,293, 115 genes, copy number 7 (broad region; genes not listed).
- chr12:66,950,754–70,920,738, 85 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:15,062,087–17,042,305, 103 genes, copy number 5 (broad region; genes not listed).
- chr17:21,197,954–27,684,144, 84 genes, copy number 5 (broad region; genes not listed).
- chr17:32,350,132–35,377,678, 86 genes, copy number 6 (broad region; genes not listed).
- chr19:14,950,034–24,163,425, 468 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
